Somatic mutation profile of tumor specimen 0DXJH2 from CCDI case PBCRGF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.3 years (1,198 days).
Specimen 0DXJH2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db80f932-6513-459a-9ea5-ee1981dec7bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXJEH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c154a47a-7bbb-4524-acb3-74f70d20a06e

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGRN | c.4367G>A p.R1456H | Missense Mutation (SNP) | VAF 135/289 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs372604628; called by muse, mutect2, varscan2
- ATRN | c.476C>T p.T159M | Missense Mutation (SNP) | VAF 103/719 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as rs1199796049; called by muse, mutect2, varscan2
- DMBT1 | c.1826A>G p.D609G | Missense Mutation (SNP) | VAF 165/701 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.033); catalogued as COSV57536535; called by muse, mutect2, varscan2
- AZIN2 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 285/576 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- PHLDB3 | c.1658G>T p.W553L | Missense Mutation (SNP) | VAF 117/467 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPL26 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 145/338 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- SLC7A7 | c.544C>A p.L182M | Missense Mutation (SNP) | VAF 171/792 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TTN | c.1511A>G p.E504G | Missense Mutation (SNP) | VAF 365/952 reads (38%) | PolyPhen benign (0.346); called by muse, mutect2, varscan2
- PTPRM | c.3424-19G>A | Intron (SNP) | VAF 202/419 reads (48%) | catalogued as rs749637336; called by muse, mutect2, varscan2
- RNASEK-C17orf49 | c.10+46G>A | Intron (SNP) | VAF 141/148 reads (95%) | called by muse, mutect2, varscan2
